Somatic mutation profile of tumor specimen TCGA-ET-A4KQ-01A (aliquot TCGA-ET-A4KQ-01A-12D-A257-08) from TCGA case TCGA-ET-A4KQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 45.7 years (16,685 days).
Specimen TCGA-ET-A4KQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb3660a8-ca24-41e1-8ffd-cd09e71fbd4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A4KQ-10A (Blood Derived Normal), aliquot TCGA-ET-A4KQ-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be9e46aa-4905-4ad6-98de-dc12727685f9

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGFG1 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100029148; called by muse, mutect2, varscan2
- FBXL20 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.288); catalogued as COSV99234617, COSV99234661; called by muse, mutect2, varscan2
- HECTD1 | c.6184G>T p.D2062Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101237489; called by muse, mutect2, varscan2
- TG | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99602865; called by muse, mutect2, varscan2
- PURA | c.442del p.L148Wfs*77 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- RAB39B | c.228C>T p.R76= | Silent (SNP) | VAF 61/209 reads (29%) | catalogued as rs782369215, COSV65624286; called by muse, mutect2, varscan2
